Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KA, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KA-01B (Primary Tumor).

[page 1 of 2]
Page 1 of 2

REPORT Tel:

Forename

Unit No

Sex

Clinical Consultant & Location

This Copy For:

SPECIMEN

Choroidal melanoma

CLINICAL DETAILS

Local resection of tumour, right eye.

MACROSCOPIC DESCRIPTION

Local resection 15 x 17 x 10mm. Scleral rim up to 2mm.

MICROSCOPY

Histological sections demonstrate a choroidal melanoma with attached adjacent normal choroid and sclera.

The tumour is pigmented and consists of a mixture of spindle and epithelioid cells. The latter occupy approx. 30% of the tumour cell population. The number of mitoses is moderately high, approx. 12/40 high power fields. The tumour cells are immunoreactive for MelanA, CD10 and for HSP-27 (score 2).

The microvasculature of the melanoma is prominent, and closed loops are focally present. Occasional "vascular seas" can also be observed: there is, however, no obvious tumour infiltration. The lymphocytic infiltrate within tumour is minimal.

There is no evident tumour extension into the sclera. The lateral resection margins are free of tumour.

DIAGNOSIS

Trans-scleral resection of a choroidal melanoma of mixed cell type.

COMMENT

Molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes

*ICD-O-3
Melanoma, epithelioid & spindle cell
mixed 8770/3
Site B Choroid C69.3
9/5/17/14*

Reported:

Pathologist:

Electronically Verified:

[page 2 of 2]
Department of Pathology

Page 2 of 2

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

1, 3, 6 and 8. Should the DNA concentration be insufficient for MLPA, microsatellite analysis will be undertaken.

A supplementary report will follow as soon as these investigations are complete.

SUPPLEMENTARY REPORT

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED], which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report.

In summary, sequence analysis demonstrated loss of chromosome 1; essentially normal chromosome 3 (note borderline loss of 2 loci - VHL and CPO); gain in chromosome 6p; and gain in chromosome 8.

These molecular data require correlation with the clinical and morphological data for metastatic risk assessment.

Reported:

Pathologist:

Electronically Verified:

Source: NCI Genomic Data Commons file 0d2b9b21-b608-4c32-8705-ec45ecdc0279 (TCGA-VD-A8KA.8741EA47-3E0A-483E-BAA2-59DE9EC904E8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).